CCDI case PBCIZW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/9bb15516-d8cd-41b2-b665-b8b46f54696a

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Embryonal carcinoma, NOS: ICD-O-3 morphology code: 9070/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.7 years (1,003 days).

Biospecimens (3 samples)
- Sample 0DTUX2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DTUX6: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DTUXA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
